Gene-level copy-number profile of tumor specimen ALCH-B40P-TTP1-A from ALCHEMIST case ALCH-B40P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.2 years (23,436 days).
Specimen ALCH-B40P-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d0dcc0a-ac9e-49a7-bc59-7d24ad188f0f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B40P-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/e6c88f53-8a54-46a9-a15e-0262ea23b1d7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 752; copy number 2: 20,290; copy number 3: 20,143; copy number 4: 11,627; copy number 5: 2,446; copy number 6: 1,416; copy number 7: 381; copy number 8: 750; copy number 9: 112; copy number 10: 19; copy number 11: 7; copy number 12: 6; copy number 14: 13; copy number 16: 37; copy number 17: 13; copy number 18: 3; copy number 19: 38; copy number 23: 1; copy number 28: 91; copy number 30: 2; copy number 33: 68; copy number 36: 84; copy number 41: 11; copy number 44: 42.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,833,229–65,067,754, 7 genes (within-gene range 0–1): JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P.
- chr2:239,943,015–239,943,094, 1 gene (within-gene range 0–3): MIR4786.
- chr2:240,954,617–240,967,451, 1 gene (within-gene range 0–3): UICLM.
- chr3:50,558,025–50,596,168, 2 genes: C3orf18, HEMK1.
- chr3:52,777,595–52,809,009, 2 genes: ITIH1, ITIH3.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:124,481,236–124,507,420, 1 gene: NR5A1.
- chr11:119,149,052–119,162,653, 1 gene: ABCG4.
- chr11:134,274,245–134,319,564, 2 genes: GLB1L3, AP000859.1.
- chr15:34,489,002–34,588,503, 6 genes: HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.
- chr17:35,400,878–35,403,006, 1 gene: AC060766.6.
- chr17:58,301,228–58,328,795, 1 gene (within-gene range 0–2): TSPOAP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,678 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–133,723, 5 genes, copy number 7–11 (within-gene range 3–11): OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3.
- chr1:39,081,316–46,482,493, 256 genes, copy number 9–44 (broad region; genes not listed).
- chr2:78,880,713–84,819,589, 52 genes, copy number 7: AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7.
- chr3:125,058,304–126,101,561, 36 genes, copy number 16: RNA5SP137, SLC12A8, RNU6-230P, MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11, AF186996.3, AF186996.2, OR7E130P, OR7E29P, OR7E93P, OR7E53P, OR7E97P, AF186996.1, AC092902.4, AC092902.2, AC092902.1, MIR548I1, RPS3AP14, SNRPCP11, LINC02614, ENPP7P4, AC092903.2, FAM86JP, ALG1L, AC092903.1, ROPN1B, SLC41A3, AC117422.1, AC079848.1.
- chr3:146,059,585–198,123,232, 908 genes, copy number 7–17 (broad region; genes not listed).
- chr7:89,754,620–92,971,299, 53 genes, copy number 7–8: RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P.
- chr11:65,726,939–66,846,552, 78 genes, copy number 8 (broad region; genes not listed).
- chr12:57,472,264–57,517,569, 2 genes, copy number 9 (within-gene range 5–9): ARHGAP9, MARS1.
- chr12:64,507,001–64,697,564, 1 gene, copy number 14 (within-gene range 6–14): RASSF3.
- chr12:64,628,344–74,402,600, 173 genes, copy number 14–41 (broad region; genes not listed).
- chr13:40,931,924–41,061,440, 2 genes, copy number 7 (within-gene range 3–7): ELF1, RGS17P1.
- chr17:46,503,946–46,509,339, 1 gene, copy number 8: RDM1P2.
- chr19:708,935–1,378,431, 45 genes, copy number 8 (within-gene range 4–8): PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C, EFNA2, RPS15P9, AC005330.1, PWWP3A.
- chr19:10,832,067–10,869,790, 3 genes, copy number 18 (within-gene range 2–18): TMED1, C19orf38, HIKESHIP2.
- chr20:35,953,617–37,445,534, 38 genes, copy number 19: SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2, DLGAP4, DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1, RBL1, RPS3AP3, RPS27AP3, AL136172.1, MROH8, AL031659.1, RPN2, GHRH, MANBAL, SRC, RPL7AP14.
- chr21:15,614,283–16,645,467, 6 genes, copy number 7–10 (within-gene range 2–10): RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P.
- chr21:16,284,696–16,539,911, 7 genes, copy number 7 (within-gene range 7–9): SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C.
- chr21:44,133,610–44,210,114, 4 genes, copy number 12 (within-gene range 2–12): GATD3A, LINC01678, AP001056.2, AP001056.1.
- chr22:18,533,646–18,653,617, 8 genes, copy number 12–23: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 736. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
